Somatic mutation profile of tumor specimen MBCProject_0504_T1_WES (aliquot MBCProject_0504_T1_WES_1) from CMI case MBCProject_0504, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 45.0 years (16,426 days).
Specimen MBCProject_0504_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1003821f-d8b8-4fc6-a821-e5889d9d02b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0504_SALIVA (Saliva), aliquot MBCProject_0504_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8760b83b-63ce-4c5f-bd35-904cd8c238cf

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Splice Region 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD22 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.723); catalogued as COSV50051103; called by muse, mutect2, varscan2
- HLA-DPA1 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs371532700; called by muse, mutect2
- PSG7 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs535481675; called by muse, mutect2, varscan2
- RBFOX1 | c.241A>G p.S81G | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV60967084; called by muse, mutect2
- RTKN2 | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1445906277; called by muse, mutect2
- STX1A | c.357+4C>T | Splice Region (SNP) | VAF 7/94 reads (7%) | catalogued as rs930291949; called by muse, mutect2
- CST3 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 34/445 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.017); called by muse, mutect2
- DNAH9 | c.8708-5_8713delinsTCTTGTTTTTT p.X2903_splice | Splice Site (ONP) | VAF 6/44 reads (14%) | called by mutect2*, pindel
- FRMPD4 | c.2731A>G p.T911A | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPP4R3C | c.559A>G p.N187D | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.041); called by muse, varscan2
- STARD13 | c.751C>T p.P251S (on ENST00000336934 / NM_001243476.3; = p.P133S on NM_052851.3) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- TM4SF5 | c.320T>G p.V107G | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF831 | c.4816C>T p.P1606S | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2
- KRT20 | c.102C>T p.S34= | Silent (SNP) | VAF 13/182 reads (7%) | catalogued as rs775867805; called by muse, mutect2
- SOWAHB | c.1515C>G p.A505= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2
- STAU1 | c.132T>A p.S44= | Silent (SNP) | VAF 22/256 reads (9%) | called by muse, mutect2
- SNRPEP2 | n.131A>C | RNA (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
